Somatic mutation profile of tumor specimen TCGA-WY-A858-01A (aliquot TCGA-WY-A858-01A-11D-A36O-08) from TCGA case TCGA-WY-A858, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 32.5 years (11,855 days).
Specimen TCGA-WY-A858-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef6c1d11-0427-473a-bc32-9f4ed553bf61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WY-A858-10A (Blood Derived Normal), aliquot TCGA-WY-A858-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e20e75a-a346-40b6-ab94-7db7bf9f0432

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 20, Silent 7, Frame Shift Del 5, In Frame Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/90 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGAP6 | c.1634G>A p.R545H (on ENST00000374056 / NM_001365867.1; = p.R568H on NM_001077665.2) | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs533152789, COSV100929051; called by muse, mutect2, varscan2
- APOH | c.65-1G>A p.X22_splice | Splice Site (SNP) | VAF 30/79 reads (38%) | catalogued as rs113836465, COSV99235594; called by muse, mutect2, varscan2
- BAZ2A | c.2731C>T p.P911S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99464938; called by muse, mutect2, varscan2
- CA12 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs763464509, COSV51605032; called by muse, mutect2, varscan2
- COL4A5 | c.4852G>T p.G1618C | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086761; called by muse, mutect2, varscan2
- CRYBG2 | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as rs567996032; called by muse, mutect2, varscan2
- DEGS2 | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV99979120; called by muse, mutect2, varscan2
- DTWD1 | c.874A>G p.K292E | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV99233531; called by muse, mutect2, varscan2
- GPR18 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.532); catalogued as COSV100540515, COSV61620972, COSV61621105; called by muse, mutect2
- HHLA2 | c.396_399del p.N132Kfs*4 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs1214163806; called by pindel, varscan2
- ITGAE | c.1925T>C p.L642P | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV99560489; called by muse, mutect2
- MAGEA8 | c.772T>A p.Y258N | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557371022, COSV99674439; called by muse, mutect2, varscan2
- MAGEE1 | c.1628T>G p.I543S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100819313; called by muse, mutect2, varscan2
- MTMR9 | c.1585G>A p.V529I | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99644027; called by muse, mutect2, varscan2
- PARD6B | c.446A>G p.D149G | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100859874; called by muse, mutect2
- PLXNC1 | c.3664_3667del p.V1222Mfs*20 | Frame Shift Del (DEL) | VAF 30/115 reads (26%) | catalogued as rs759208451; called by mutect2, pindel, varscan2
- PTPN23 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754253770, COSV99650264, COSV99650762; called by muse, mutect2, varscan2
- SLC9C1 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156646671, COSV59895077, COSV99997462; called by muse, mutect2, varscan2
- SMOC1 | c.449del p.S150Lfs*18 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | catalogued as COSV62762704; called by mutect2, pindel, varscan2
- SNX25 | c.1780T>C p.S594P | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99252454; called by muse, mutect2, varscan2
- TTN | c.83742G>C p.W27914C (on ENST00000591111; = p.W20490C on NM_003319.4) | Missense Mutation (SNP) | VAF 34/126 reads (27%) | PolyPhen probably damaging (0.999); catalogued as COSV100598150; called by muse, mutect2, varscan2
- VNN1 | c.265A>G p.R89G | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100907693; called by muse, mutect2, varscan2
- ADGRB1 | c.3077_3079del p.F1026del | In Frame Del (DEL) | VAF 10/25 reads (40%) | called by mutect2, varscan2
- ALCAM | c.1169_1170del p.Y390Cfs*10 | Frame Shift Del (DEL) | VAF 27/123 reads (22%) | called by mutect2, pindel, varscan2
- ATRX | c.4070del p.K1357Rfs*18 | Frame Shift Del (DEL) | VAF 40/148 reads (27%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.3079_3081del p.K1027del | In Frame Del (DEL) | VAF 15/46 reads (33%) | called by pindel, varscan2
- FBXO24 | c.432T>C p.D144= (on ENST00000241071 / NM_033506.3; = p.D182= on NM_012172.5) | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV99575036; called by muse, mutect2, varscan2
- KIF9 | c.816C>G p.L272= | Silent (SNP) | VAF 41/130 reads (32%) | catalogued as rs746914227, COSV99646434; called by muse, mutect2, varscan2
- MADCAM1 | c.345G>A p.P115= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1305066293, COSV53131488; called by muse, mutect2, varscan2
- MAGEC1 | c.3297T>C p.F1099= | Silent (SNP) | VAF 57/266 reads (21%) | catalogued as COSV99595023; called by muse, mutect2, varscan2
- MKS1 | c.225G>A p.E75= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100439475; called by muse, mutect2, varscan2
- OR6C3 | c.507C>T p.N169= | Silent (SNP) | VAF 45/214 reads (21%) | catalogued as rs375250219; called by muse, mutect2, varscan2
- PLD2 | c.1266G>A p.L422= | Silent (SNP) | VAF 42/182 reads (23%) | catalogued as COSV99562088; called by muse, mutect2, varscan2
